Surgical pathology report (de-identified scan), TCGA case TCGA-26-5134, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-5134-01A (Primary Tumor).

[page 1 of 2]
A. Left brain mass (██████7) A. KI-67, Nuclear Antigen, Mib1(██████)
A. Glial Fibrill. Acid Prt (██████) A. 1P19q Malignant
Glioma Anaysis (██████7) A. 1P19q Malignant Glioma Analysis, add
(██████) x 3 A. P53 Protein (88342) A. Frozen Section Charge (██████)

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and hospital #:

A. The specimen is received fresh, labeled "brain lesion" and consists of two rectangular pieces of cerebral cortex with underlying subcortical white matter. Each piece of tissue measures 4.2 x 4.0 x 1.1 cm and 4.1 x 3.0 x 1.4 cm. The meningeal surfaces are smooth and beige-tan, with a fine reticulated vasculature. The resection margin is cauterized and focally necrotic. Sectioning reveals a clear demarcation between the gray and white matter layers. No discrete lesion is identified, however, there is focal discoloration of the white matter. A representative section of this discolored white matter is submitted for frozen section. Frozen section diagnosis is "Malignant glioma," per [REDACTED]. The frozen section tissue is submitted for permanent processing in cassette FSA1. Additional representative sections are submitted in cassettes A2-A7. ([REDACTED])

A. "Left brain mass":

COMMENT: This high grade glioma features areas of high cellularity, mitoses, vascular endothelial proliferation and necrosis. The areas of necrosis with apparent pseudopalisading are best represented in slide "A1". Additional rather circumscribed foci of high grade oligodendrogliomatous appearance are also seen. In such areas, the Ki-67 labeling index is 20-30%. P53 is reactive in about 20% of tumor cell nuclei. GFAP is reactive in some tumor cells and in reactive-appearing astrocytes. These results support the diagnosis.

Resident/Prosector/Pathologist:

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
[REDACTED]
Pathologist

Electronically signed [REDACTED]
[REDACTED]

Pathologist

Electronically signed [REDACTED]

CHROMOSOMES 1P AND 19Q ANALYSIS:

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) WAS PERFORMED ON REPRESENTATIVE
PARAFFIN-EMBEDDED TUMOR TISSUE (VYSIS).

IN THIS CASE, NO DELETIONS OF 1P OR 19Q WERE IDENTIFIED.

PLEASE REFER TO UF DIAGNOSTIC-REFERENCE LABORATORIES REPORT: [REDACTED] FOR
FURTHER DETAILS OF THIS ANALYSIS.

REFERENCES:

[REDACTED]

Source: NCI Genomic Data Commons file ffa8ee1a-fc7b-4050-84a3-39b3422191b8 (TCGA-26-5134.BC937071-CA55-4002-B4FA-44326BE2AC1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).